Somatic mutation profile of tumor specimen TARGET-30-PATKSX-01A (aliquot TARGET-30-PATKSX-01A-01D) from TARGET case TARGET-30-PATKSX, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 9.4 years (3,444 days).
Specimen TARGET-30-PATKSX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08feda56-a9be-4403-b9b5-0def3bd9fffe.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATKSX-10A (Blood Derived Normal), aliquot TARGET-30-PATKSX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d43fed3a-af27-4add-872b-31e20f153771

The open-access MAF lists 5 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 2, Silent 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC168 | c.2767G>T p.G923C | Missense Mutation (SNP) | VAF 73/404 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- CCDC168 | c.7497C>T p.S2499= | Silent (SNP) | VAF 100/466 reads (21%) | catalogued as COSV101468960, COSV70555442; called by muse, mutect2, varscan2
- SIN3A | c.1080C>A p.A360= | Silent (SNP) | VAF 38/159 reads (24%) | catalogued as COSV64583687; called by muse, mutect2, varscan2
- VANGL1 | c.*326G>A | 3'UTR (SNP) | VAF 105/239 reads (44%) | catalogued as rs989019015, COSV59621073; called by muse, mutect2, varscan2
- ZNF469 | c.*1316C>T | 3'UTR (SNP) | VAF 8/171 reads (5%) | catalogued as rs980575920, COSV71259488; called by muse, mutect2
